Somatic mutation profile of tumor specimen TCGA-MO-A47P-01A (aliquot TCGA-MO-A47P-01A-11D-A24N-09) from TCGA case TCGA-MO-A47P, project TCGA-SARC (Sarcoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Liposarcoma, well differentiated; Tissue or organ of origin: Retroperitoneum; Age at diagnosis: 37.7 years (13,765 days).
Specimen TCGA-MO-A47P-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) a9714994-8879-4953-bf3c-5fac64f12ca5.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-MO-A47P-10A (Blood Derived Normal), aliquot TCGA-MO-A47P-10A-01D-A24N-09; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/5d9cce60-9798-4103-8d81-d69f8596edd7

The open-access MAF lists 11 somatic variants for this specimen: 11 protein-altering or splice-affecting.
By variant classification: Missense Mutation 8, Splice Site 2, Frame Shift Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ATM | c.1186A>C p.I396L | Missense Mutation (SNP) | VAF 3/25 reads (12%) | SIFT tolerated (0.61); PolyPhen benign (0.015); catalogued as COSV99590406; called by muse, mutect2
- ATP2A1 | c.316G>A p.V106I | Missense Mutation (SNP) | VAF 34/127 reads (27%) | SIFT tolerated (0.07); PolyPhen benign (0.057); catalogued as rs772383454, COSV100837326; called by muse, mutect2, varscan2
- BPIFB4 | c.1045G>A p.V349M | Missense Mutation (SNP) | VAF 18/68 reads (26%) | SIFT tolerated (0.2); PolyPhen probably damaging (0.981); catalogued as rs761710384, COSV100971575; called by muse, mutect2, varscan2
- HNF4G | c.1049C>T p.T350I (on ENST00000354370 / NM_001330561.2; = p.T397I on NM_004133.5) | Missense Mutation (SNP) | VAF 18/48 reads (38%) | SIFT tolerated (0.33); PolyPhen benign (0.011); catalogued as COSV100584727; called by muse, mutect2, varscan2
- INTS3 | c.432+1G>A p.X144_splice | Splice Site (SNP) | VAF 7/25 reads (28%) | catalogued as COSV100016263; called by muse, mutect2, varscan2
- IRAK4 | c.1108A>T p.I370F | Missense Mutation (SNP) | VAF 14/51 reads (27%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.97); catalogued as COSV101471831; called by muse, mutect2, varscan2
- PRICKLE2 | c.581A>G p.N194S (on ENST00000295902; = p.N138S on NM_198859.4) | Missense Mutation (SNP) | VAF 11/24 reads (46%) | SIFT tolerated (0.15); PolyPhen benign (0.019); catalogued as rs1247504361, COSV55762940; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- TYMS | c.853G>C p.V285L | Missense Mutation (SNP) | VAF 13/34 reads (38%) | SIFT tolerated (0.11); PolyPhen benign (0.315); catalogued as COSV99201103; called by muse, mutect2, varscan2
- ITGA6 | c.2895+2_2895+16del p.X965_splice (on ENST00000442250; = p.X926_splice on NM_000210.4 and 1 other RefSeq transcript) | Splice Site (DEL) | VAF 4/38 reads (11%) | called by mutect2, pindel
- SLC12A4 | c.1735C>A p.P579T | Missense Mutation (SNP) | VAF 3/44 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.964); called by muse, mutect2
- TSC2 | c.1040del p.K347Rfs*16 | Frame Shift Del (DEL) | VAF 28/77 reads (36%) | called by mutect2, pindel, varscan2
